Somatic mutation profile of tumor specimen ALCH-B1LS-TTP1-A (aliquot ALCH-B1LS-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B1LS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.4 years (22,784 days).
Specimen ALCH-B1LS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e53f9a4e-bc4e-4257-85ea-79702f76fe95.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1LS-NB1-A (Blood Derived Normal), aliquot ALCH-B1LS-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9e84b6e-e812-403f-aae8-6d650e4b548e

The open-access MAF lists 24 somatic variants for this specimen: 19 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 2, Splice Region 1, Intron 1, 5'UTR 1, Splice Site 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 121/637 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 117/458 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: pathogenic / likely pathogenic / uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TPM3 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 61/759 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs121964852, CM072092; ClinVar: pathogenic; called by muse, mutect2
- CDH4 | c.2450G>A p.R817H | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as rs376638308; called by muse, mutect2, varscan2
- CSAD | c.478G>A p.V160I (on ENST00000444623 / NM_001244705.2; = p.V187I on NM_015989.5) | Missense Mutation (SNP) | VAF 71/346 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1335268558; called by muse, mutect2, varscan2
- GAPDHS | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 14/181 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.64); catalogued as rs750502242, COSV55880079; called by muse, mutect2
- OTOF | c.2039G>A p.G680E | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.033); catalogued as rs751952710; called by muse, mutect2, varscan2
- BST2 | c.106_111del p.I36_L37del | In Frame Del (DEL) | VAF 57/381 reads (15%) | called by mutect2, pindel, varscan2
- CIP2A | c.1445C>G p.T482S | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- EYS | c.1300-1G>T p.X434_splice | Splice Site (SNP) | VAF 36/385 reads (9%) | called by muse, mutect2
- FANCM | c.685G>A p.V229I | Missense Mutation (SNP) | VAF 62/281 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- IVL | c.834G>C p.E278D | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.029); called by muse, mutect2
- MCM3 | c.923A>T p.Q308L (on ENST00000229854 / NM_001366374.2; = p.Q298L on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MCM8 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 71/418 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- NUP205 | c.4624C>T p.P1542S | Missense Mutation (SNP) | VAF 36/255 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- PNPT1 | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 14/336 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- PZP | c.1198C>A p.L400I | Missense Mutation (SNP) | VAF 28/353 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.566); called by muse, mutect2
- SLC49A4 | c.121G>A p.V41I | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.005); called by muse, mutect2
- ZFAND2B | c.729+8G>C | Splice Region (SNP) | VAF 18/224 reads (8%) | called by muse, mutect2
- HTRA3 | c.1089G>A p.T363= | Silent (SNP) | VAF 37/356 reads (10%) | catalogued as rs775609101, COSV100246611; called by muse, mutect2, varscan2
- L1TD1 | c.2430C>G p.V810= | Silent (SNP) | VAF 34/160 reads (21%) | called by muse, mutect2, varscan2
- MTCH1 | c.-56C>A | 5'UTR (SNP) | VAF 11/102 reads (11%) | called by muse, mutect2, varscan2
- TEKT4P2 | n.1348G>A | RNA (SNP) | VAF 24/247 reads (10%) | called by muse, mutect2, varscan2
- TNFAIP8 | c.32-1366T>C | Intron (SNP) | VAF 28/302 reads (9%) | catalogued as rs940105598; called by muse, mutect2
